Somatic mutation profile of tumor specimen C3L-02662-02 (aliquot CPT0267260007) from CPTAC case C3L-02662, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.5 years (23,940 days).
Specimen C3L-02662-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fff17b33-c488-4ad9-875c-288aed8f3c2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02662-31 (Blood Derived Normal), aliquot CPT0267300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/374481f2-31b3-4669-99ef-e783f0a9d32e

The open-access MAF lists 86 somatic variants for this specimen: 57 protein-altering or splice-affecting, 20 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 20, Intron 5, RNA 3, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.209+1G>A p.X70_splice | Splice Site (SNP) | VAF 16/40 reads (40%) | hotspot (GDC flag); catalogued as rs1554897280, CD004539, CS110217, CS991490, CS992480, COSV64288452, COSV64288759, COSV64291888, COSV64298333; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as rs121913301, CM951105, CM961226, COSV57296833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 96/326 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 50/217 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- ADGB | c.4594C>T p.R1532* | Nonsense Mutation (SNP) | VAF 15/73 reads (21%) | catalogued as COSV58847400; called by muse, mutect2, varscan2
- BCL9 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782456888; called by muse, mutect2, varscan2
- CCNT1 | c.1940A>G p.N647S | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.037); catalogued as rs747855198; called by muse, mutect2, varscan2
- CCR6 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 94/315 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs774906837; called by muse, mutect2, varscan2
- CD163 | c.3238C>T p.R1080W | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as rs749974365, COSV63130419; called by muse, mutect2, varscan2
- CD163 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 97/352 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs372647561; called by muse, mutect2, varscan2
- CEACAM8 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 28/226 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as rs372473875; called by muse, mutect2, varscan2
- CNGA4 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770277700, COSV66005755, COSV66006249; called by muse, mutect2, varscan2
- COL27A1 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs137868129; called by muse, mutect2, varscan2
- DDX19A | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 91/381 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.167); catalogued as rs773246101; called by muse, mutect2, varscan2
- DDX60L | c.3611C>T p.A1204V | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.444); catalogued as rs1324219503; called by muse, mutect2, varscan2
- DVL2 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.311); catalogued as rs537514398; called by muse, mutect2, varscan2
- EPPK1 | c.2579C>T p.T860M | Missense Mutation (SNP) | VAF 67/233 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs375593815; called by muse, mutect2, varscan2
- FIG4 | c.1039+6T>C | Splice Region (SNP) | VAF 30/117 reads (26%) | catalogued as rs985655815; called by muse, mutect2, varscan2
- GRM8 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs780348891, COSV58805362, COSV58831333; called by muse, mutect2, varscan2
- HCK | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 40/229 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.657); catalogued as rs761716878, COSV52944469; called by muse, mutect2, varscan2
- HECW1 | c.1930G>A p.A644T | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs1272735976, COSV67837401; called by muse, mutect2, varscan2
- HTR5A | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV55284798; called by muse, mutect2, varscan2
- ICA1 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 130/510 reads (25%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.472); catalogued as rs757253043; called by muse, mutect2, varscan2
- IGFL2 | c.79G>A p.A27T (on ENST00000377693 / NM_001135113.2; = p.A38T on NM_001002915.2) | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs572431190, COSV66616652; called by muse, mutect2, varscan2
- INTS1 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 55/268 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197348390; called by muse, mutect2, varscan2
- KCNU1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs561683935, COSV67757944; called by muse, mutect2, varscan2
- MYH11 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs768807804, COSV55543701; called by muse, mutect2, varscan2
- OR52N5 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs371946025; called by muse, mutect2, varscan2
- PGLYRP4 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs750203517; called by muse, mutect2, varscan2
- RABEP1 | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372513782, COSV99336849; called by muse, mutect2, varscan2
- SEMA4B | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772058869, COSV60173535; called by muse, mutect2, varscan2
- SEMA6B | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as rs768420508, COSV100014970; called by muse, mutect2, varscan2
- SLIT2 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.154); catalogued as rs755144502, COSV56588418; called by muse, mutect2, varscan2
- TNFRSF8 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 95/285 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55801047; called by muse, mutect2, varscan2
- TRIM51 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV55267456, COSV99792480; called by muse, mutect2, varscan2
- ZSCAN1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 138/532 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs779306454, COSV99991467; called by muse, mutect2, varscan2
- ADAM28 | c.1798G>T p.V600L | Missense Mutation (SNP) | VAF 60/199 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD20A1 | c.2985G>C p.K995N | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- BRD1 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTN3A3 | c.1640C>T p.P547L | Missense Mutation (SNP) | VAF 58/240 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BVES | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- CD177 | c.647C>T p.T216I | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRISPLD2 | c.192C>A p.N64K | Missense Mutation (SNP) | VAF 130/487 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP4F2 | c.406C>A p.L136I | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- FAT2 | c.1570C>T p.L524F | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM4 | c.2302A>T p.T768S | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- HSPB3 | c.433G>T p.D145Y | Missense Mutation (SNP) | VAF 84/364 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MUC5B | c.11714C>A p.T3905N | Missense Mutation (SNP) | VAF 76/373 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.452); called by muse, mutect2
- MXRA5 | c.7444G>A p.E2482K | Missense Mutation (SNP) | VAF 99/192 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OVGP1 | c.592G>A p.V198M | Missense Mutation (SNP) | VAF 68/221 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PIH1D2 | c.528_529del p.E178Kfs*47 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | called by mutect2, pindel
- PNLIPRP2 | c.1066+2T>C p.X356_splice | Splice Site (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- PTPN3 | c.1013_1019del p.N338Ifs*5 | Frame Shift Del (DEL) | VAF 22/155 reads (14%) | called by mutect2, pindel, varscan2
- REV3L | c.2416_2419del p.N806Vfs*24 | Frame Shift Del (DEL) | VAF 24/108 reads (22%) | called by mutect2, pindel, varscan2
- SLC26A3 | c.2113A>C p.K705Q | Missense Mutation (SNP) | VAF 28/243 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SP100 | c.1316C>G p.S439C | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); called by muse, mutect2
- XKR9 | c.779A>C p.E260A | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK1 | c.309C>T p.N103= | Silent (SNP) | VAF 83/321 reads (26%) | catalogued as rs778974540, COSV99224698; called by muse, mutect2, varscan2
- CFH | c.465A>G p.G155= | Silent (SNP) | VAF 38/119 reads (32%) | called by muse, mutect2, varscan2
- DCAF12L1 | c.199A>C p.R67= | Silent (SNP) | VAF 60/101 reads (59%) | called by muse, mutect2, varscan2
- DIS3L2 | c.1491A>G p.A497= | Silent (SNP) | VAF 63/324 reads (19%) | called by muse, mutect2, varscan2
- DNAH5 | c.1419C>T p.F473= | Silent (SNP) | VAF 76/279 reads (27%) | catalogued as rs373172723; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCP | c.1197C>T p.C399= (on ENST00000620378; = p.C456= on NM_001366122.1) | Silent (SNP) | VAF 61/256 reads (24%) | catalogued as rs567771266; called by muse, mutect2, varscan2
- LY6G5C | c.504C>T p.H168= (on ENST00000375863; = p.H93= on NM_025262.3) | Silent (SNP) | VAF 52/172 reads (30%) | catalogued as rs994004504; called by muse, mutect2
- MIB2 | c.2742C>T p.G914= | Silent (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- NPHS1 | c.3201C>T p.F1067= | Silent (SNP) | VAF 77/331 reads (23%) | catalogued as rs749058353, COSV62287667; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB11 | c.168G>A p.V56= | Silent (SNP) | VAF 82/296 reads (28%) | called by muse, mutect2, varscan2
- PCSK6 | c.933C>T p.D311= | Silent (SNP) | VAF 84/260 reads (32%) | catalogued as rs567006763, COSV100083994; called by muse, mutect2, varscan2
- PKDREJ | c.1275C>T p.G425= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as rs377483844; called by muse, mutect2, varscan2
- RBM47 | c.93C>T p.N31= | Silent (SNP) | VAF 74/283 reads (26%) | catalogued as rs748709342, COSV55938962; called by muse, mutect2, varscan2
- SEMA6C | c.2181C>T p.N727= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV58999809; called by muse, mutect2, varscan2
- SLC8A3 | c.60C>T p.T20= | Silent (SNP) | VAF 36/135 reads (27%) | catalogued as rs759277151, COSV100775791; called by muse, mutect2, varscan2
- THSD4 | c.369G>A p.A123= | Silent (SNP) | VAF 150/459 reads (33%) | called by muse, mutect2, varscan2
- TMEM94 | c.2643C>T p.L881= | Silent (SNP) | VAF 65/179 reads (36%) | catalogued as rs1289379335; called by muse, mutect2, varscan2
- TRAFD1 | c.1530C>T p.H510= | Silent (SNP) | VAF 74/285 reads (26%) | catalogued as rs1056149511; called by muse, mutect2, varscan2
- TRIM43B | c.363C>T p.H121= | Silent (SNP) | VAF 43/253 reads (17%) | catalogued as rs1257168391; called by muse, mutect2, varscan2
- ZIM2 | c.1008C>A p.T336= | Silent (SNP) | VAF 64/252 reads (25%) | catalogued as COSV55633410; called by muse, mutect2, varscan2
- AC006372.4 | n.444G>A | RNA (SNP) | VAF 58/393 reads (15%) | called by muse, mutect2, varscan2
- ALDH3B2 | c.873+14C>T | Intron (SNP) | VAF 39/190 reads (21%) | catalogued as rs748524121; called by muse, mutect2, varscan2
- DEUP1 | c.*25_*26insA | 3'UTR (INS) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- ISCA1P1 | n.64C>T | RNA (SNP) | VAF 54/155 reads (35%) | called by muse, mutect2, varscan2
- LYPD3 | c.383-134C>T | Intron (SNP) | VAF 38/291 reads (13%) | called by muse, mutect2, varscan2
- MCF2L | c.368+2259C>A | Intron (SNP) | VAF 71/296 reads (24%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109986C>A | Intron (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- PKD1L2 | n.733G>A | RNA (SNP) | VAF 26/66 reads (39%) | catalogued as rs375342800; called by muse, mutect2, varscan2
- PRKCB | c.1864-5182T>C | Intron (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
